Surgical pathology report (de-identified scan), TCGA case TCGA-19-1389, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Case Western, specimen TCGA-19-1389-02A (Recurrent Tumor).

SURGICAL PATHOLOGY REPORT

Name:
Accession #:
Date of Procedure:
Date Received:
Submitting Physician:

Med. Rec #.
Location:
Race: CAUCASIAN
DOB/Sex: (Age:) / M

FINAL DIAGNOSIS

- A. LEFT UPPER FRONTAL LOBE OF BRAIN, TUMOR, BIOPSY:
-- RECURRENT/RESIDUAL GLIOMA DEMONSTRATING AN ORGANIZING HEMORRHAGE AND NECROSIS.
- B., C. LEFT TEMPORAL AND FRONTAL LOBES OF BRAIN, TUMOR, REMOVAL:
-- GIANT CELL GLIOBLASTOMA MULTIFORME (WHO GRADE IV).

Electronically Signed Out By By the signature on this report, the individual or group listed as making the Final Interpretation/Diagnosis certifies that they have reviewed this case.

Intraoperative Consultation:

- A: Touch Imprint: Malignant glioma with necrosis.
B: Microscopic: Giant cell glioblastoma.

Clinical History:

Recurrent (I) frontal brain tumor

Specimens Submitted As:

- A: brain tumor left upper frontal lobe
B: brain tumor left temporal lobe
C: BRAIN TUMOR (L) FRONTAL

ICD-0-3
Glioblastoma multiforme 9440/3
Site: brain, NOS C71.9 6/12/15

Gross Description:

A: Received fresh for intraoperative consultation, labelled with the patient's name and number, and "brain tumor left upper frontal lobe", are multiple, small, pink-tan soft tissue fragments, 0.4 x 0.2 x 0.2 cm in aggregate. Representative sections are submitted for touch imprint. The remaining of the tissue is submitted entirely for permanents.

B: Received fresh for intraoperative consultation, labelled with the patient's name and number, and "brain tumor left temporal lobe", are multiple, small, pink-tan soft tissue fragments, 0.5 x 0.3 x 0.2 cm in aggregate. Representative sections are submitted for touch imprint. The remaining of the tissue is submitted entirely for permanents.

C: Received in formalin, labeled with the patient's name and number, are multiple light tan to red-brown irregular soft tissue fragments measuring 2.8 x 2 x 0.7 cm in aggregate. Submitted in toto in one cassette.

Source: NCI Genomic Data Commons file 4d894025-2bd3-4b3b-87db-b8d25b925896 (TCGA-19-1389.3D1C69CB-761A-475B-9F7F-B045C5DA634E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).